Somatic mutation profile of tumor specimen C3L-06474-05 (aliquot CPT0433950006) from CPTAC case C3L-06474, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 63.0 years (23,015 days).
Specimen C3L-06474-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b34b0c8-7766-4d0c-9c49-d7a043a83500.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06474-31 (Blood Derived Normal), aliquot CPT0434060005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85dab5ad-3d74-4778-a377-8265e7eada7c

The open-access MAF lists 109 somatic variants for this specimen: 82 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 24, Nonsense Mutation 8, Frame Shift Ins 2, RNA 1, Frame Shift Del 1, Nonstop Mutation 1, Intron 1, In Frame Del 1, Translation Start Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK1 | c.4153C>T p.R1385* | Nonsense Mutation (SNP) | VAF 51/433 reads (12%) | catalogued as rs750820522; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 88/458 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1634A>G p.E545G | Missense Mutation (SNP) | VAF 51/234 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAN | c.1955C>T p.T652M | Missense Mutation (SNP) | VAF 60/561 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs373373120; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTRT1 | c.320T>G p.L107R | Missense Mutation (SNP) | VAF 79/314 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64418999, COSV64419064; called by muse, mutect2, varscan2
- AGXT | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 42/372 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM001055, COSV100280076; called by muse, mutect2, varscan2
- ARHGDIA | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1426856429; called by muse, mutect2
- C9orf64 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 64/541 reads (12%) | catalogued as rs201772510, COSV59032734; called by muse, mutect2, varscan2
- CASKIN1 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 43/366 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs551345537; called by muse, mutect2, varscan2
- CEBPZ | c.2179G>A p.V727M | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs767993948; called by muse, mutect2
- CLGN | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs376735755; called by muse, mutect2, varscan2
- CRACD | c.3494G>A p.R1165H | Missense Mutation (SNP) | VAF 65/491 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.381); catalogued as rs771063487; called by muse, mutect2, varscan2
- DLGAP2 | c.2465G>A p.R822Q | Missense Mutation (SNP) | VAF 36/856 reads (4%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.988); catalogued as rs765947691, COSV101421035; called by muse, mutect2
- DNAH17 | c.8636G>A p.G2879E | Missense Mutation (SNP) | VAF 65/461 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774363922; called by muse, mutect2, varscan2
- DOK3 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 42/309 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.777); catalogued as rs1480485056; called by muse, mutect2, varscan2
- EEF2KMT | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 40/356 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs748917479; called by muse, mutect2, varscan2
- ELOA2 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 26/656 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs963166141, COSV55295168; called by muse, mutect2
- GPR85 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 45/447 reads (10%) | SIFT tolerated (0.92); PolyPhen benign (0.028); catalogued as rs756442417, COSV51782887; called by muse, mutect2
- GRM7 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 22/640 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs1174647125; called by muse, mutect2
- GRM8 | c.2453T>G p.L818R | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV58829629, COSV58836480; called by muse, mutect2, varscan2
- HCN1 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57529468; called by muse, mutect2, varscan2
- HIVEP2 | c.253C>A p.P85T | Missense Mutation (SNP) | VAF 60/480 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV50008607, COSV50090418; called by muse, mutect2, varscan2
- KLHL1 | c.1687G>T p.G563C | Missense Mutation (SNP) | VAF 49/437 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100917147; called by muse, mutect2, varscan2
- MAP10 | c.2803A>G p.S935G | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs749192832; called by muse, mutect2
- MBD5 | c.3532G>A p.E1178K | Missense Mutation (SNP) | VAF 52/396 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.127); catalogued as rs571209967, COSV68696564; ClinVar: likely benign; called by muse, mutect2, varscan2
- MRC1 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 65/491 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.952); catalogued as rs782704717; called by muse, mutect2, varscan2
- MYO1C | c.1049G>A p.R350Q (on ENST00000648651 / NM_001080779.2; = p.R315Q on NM_033375.5) | Missense Mutation (SNP) | VAF 60/436 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs751264944, COSV62998318; called by muse, mutect2, varscan2
- NEFL | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 58/320 reads (18%) | catalogued as rs201616934; called by muse, mutect2, varscan2
- NOS3 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 47/310 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as rs764271277, COSV52488685; called by muse, mutect2, varscan2
- OSBPL10 | c.83G>A p.G28D | Missense Mutation (SNP) | VAF 28/592 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1327715534; called by muse, mutect2
- PAXIP1 | c.2623G>T p.E875* | Nonsense Mutation (SNP) | VAF 39/232 reads (17%) | catalogued as COSV68185996; called by mutect2, varscan2
- PCDHGA1 | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 83/639 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.166); catalogued as rs550952748, COSV65296095; called by muse, mutect2, varscan2
- PLCB1 | c.3478G>A p.E1160K | Missense Mutation (SNP) | VAF 60/500 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100570186; called by muse, mutect2, varscan2
- PRKAG1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 35/326 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs780637267, COSV60292088; called by muse, mutect2, varscan2
- RGL2 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 100/679 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.185); catalogued as rs778787902; called by muse, mutect2, varscan2
- ROCK1 | c.3449T>A p.I1150N | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67695579; called by muse, mutect2, varscan2
- RUNDC3B | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 137/560 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as rs1173051243, COSV56692938; called by muse, mutect2, varscan2
- SMARCA4 | c.2539C>T p.Q847* | Nonsense Mutation (SNP) | VAF 45/426 reads (11%) | catalogued as COSV60792024; called by muse, mutect2, varscan2
- SMARCA4 | c.2738C>T p.P913L | Missense Mutation (SNP) | VAF 59/465 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs778175819, COSV60785488, COSV60786996; called by muse, mutect2, varscan2
- SPEF2 | c.3304A>G p.K1102E | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs200371753; called by muse, varscan2
- TSPAN10 | c.1147G>A p.G383S (on ENST00000574882 / NM_001290212.1; = p.G345S on NM_031945.4) | Missense Mutation (SNP) | VAF 43/359 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs1195275386; called by muse, mutect2, varscan2
- WWOX | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 47/405 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs749277249, COSV68347995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA7 | c.1154G>A p.S385N | Missense Mutation (SNP) | VAF 71/527 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AP002512.3 | c.542C>T p.T181I | Missense Mutation (SNP) | VAF 48/362 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- ASPM | c.5087A>C p.K1696T | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CEP85L | c.698A>G p.E233G | Missense Mutation (SNP) | VAF 35/324 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- COL12A1 | c.6203A>C p.D2068A | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- DNHD1 | c.13732G>A p.E4578K | Missense Mutation (SNP) | VAF 71/499 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DPPA4 | c.780G>T p.K260N | Missense Mutation (SNP) | VAF 47/429 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- EIF4G3 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 28/317 reads (9%) | called by muse, mutect2
- FGL2 | c.1318T>A p.*440Kext*22 | Nonstop Mutation (SNP) | VAF 22/332 reads (7%) | called by muse, mutect2
- HEG1 | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 15/385 reads (4%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); called by muse, mutect2
- HJURP | c.1858A>G p.T620A | Missense Mutation (SNP) | VAF 56/421 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGF1R | c.341A>G p.N114S | Missense Mutation (SNP) | VAF 18/594 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.142); called by muse, mutect2
- IGHD2-8 | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 12/280 reads (4%) | called by muse, mutect2
- IL13RA2 | c.772T>A p.W258R | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT19 | c.1104_1105insCTCA p.I369Lfs*70 | Frame Shift Ins (INS) | VAF 68/602 reads (11%) | called by mutect2, varscan2*
- LRRC75B | c.-1_13del | Translation Start Site (DEL) | VAF 34/129 reads (26%) | called by mutect2, pindel, varscan2
- LZTS2 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 68/524 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); called by muse, varscan2
- MAP3K9 | c.1637G>C p.R546P | Missense Mutation (SNP) | VAF 56/575 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- MAPK7 | c.2225_2227del p.G742del | In Frame Del (DEL) | VAF 56/468 reads (12%) | called by mutect2, pindel, varscan2
- MED28 | c.146A>G p.E49G | Missense Mutation (SNP) | VAF 54/402 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYPOP | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 59/584 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NKX6-1 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 16/492 reads (3%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.08); called by muse, mutect2
- PAX9 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 62/454 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- PCDHA12 | c.992C>A p.A331E | Missense Mutation (SNP) | VAF 22/522 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.589); called by muse, mutect2
- PCDHGA1 | c.1118A>T p.D373V | Missense Mutation (SNP) | VAF 42/400 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGC | c.331dup p.S111Kfs*36 | Frame Shift Ins (INS) | VAF 35/299 reads (12%) | called by mutect2, pindel, varscan2
- POLA1 | c.2428A>G p.R810G | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- PPFIA2 | c.1474G>T p.E492* | Nonsense Mutation (SNP) | VAF 22/162 reads (14%) | called by mutect2, varscan2
- RANBP17 | c.3213G>C p.E1071D | Missense Mutation (SNP) | VAF 52/346 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RIMS1 | c.4414A>G p.T1472A | Missense Mutation (SNP) | VAF 14/534 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- SENP7 | c.1062A>T p.E354D | Missense Mutation (SNP) | VAF 32/288 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SMO | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 55/408 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SNAP25 | c.269G>T p.C90F | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.243); called by muse, mutect2
- SPOP | c.615T>A p.C205* | Nonsense Mutation (SNP) | VAF 39/348 reads (11%) | called by muse, mutect2, varscan2
- SPTBN5 | c.9412G>A p.E3138K | Missense Mutation (SNP) | VAF 41/351 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- TDP2 | c.1032_1033del p.C344Wfs*2 | Frame Shift Del (DEL) | VAF 37/346 reads (11%) | called by pindel, varscan2
- TRIML2 | c.299A>C p.N100T | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- TSC2 | c.3160G>T p.G1054C | Missense Mutation (SNP) | VAF 43/370 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBAC1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.228); called by muse, varscan2
- UGT1A8 | c.685G>C p.E229Q | Missense Mutation (SNP) | VAF 40/300 reads (13%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ABRA | c.12C>T p.G4= | Silent (SNP) | VAF 33/342 reads (10%) | catalogued as rs753793249, COSV61732087; called by muse, mutect2
- ADAMTS2 | c.2688C>T p.A896= | Silent (SNP) | VAF 47/424 reads (11%) | catalogued as rs370747086, COSV52371745; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKDD1B | c.141G>A p.P47= | Silent (SNP) | VAF 58/612 reads (9%) | called by muse, mutect2
- ANXA4 | c.15C>G p.T5= | Silent (SNP) | VAF 15/345 reads (4%) | called by muse, mutect2
- CACNA1C | c.5055G>A p.E1685= | Silent (SNP) | VAF 50/424 reads (12%) | called by muse, mutect2, varscan2
- DCBLD2 | c.1713C>T p.D571= | Silent (SNP) | VAF 52/312 reads (17%) | catalogued as COSV58792223; called by muse, mutect2, varscan2
- GRIA1 | c.330G>A p.T110= | Silent (SNP) | VAF 53/393 reads (13%) | catalogued as rs370782311, COSV53588479; called by muse, mutect2, varscan2
- HNRNPD | c.930A>G p.Q310= (on ENST00000313899 / NM_031370.3; = p.Q291= on NM_031369.2) | Silent (SNP) | VAF 42/361 reads (12%) | called by muse, mutect2, varscan2
- KCNAB1 | c.405C>T p.L135= (on ENST00000490337 / NM_172160.3; = p.L124= on NM_003471.3) | Silent (SNP) | VAF 31/383 reads (8%) | catalogued as COSV56749391; called by muse, mutect2
- LTB | c.97T>C p.L33= | Silent (SNP) | VAF 20/748 reads (3%) | called by muse, mutect2
- MANSC4 | c.1011G>A p.E337= | Silent (SNP) | VAF 24/229 reads (10%) | called by muse, mutect2, varscan2
- OR8J3 | c.102C>T p.L34= | Silent (SNP) | VAF 44/518 reads (8%) | catalogued as rs1381881345; called by muse, mutect2
- PSPC1 | c.789A>G p.P263= | Silent (SNP) | VAF 22/342 reads (6%) | called by muse, mutect2
- PXDN | c.2028A>G p.G676= | Silent (SNP) | VAF 94/439 reads (21%) | called by muse, mutect2, varscan2
- RBM33 | c.3231C>G p.G1077= | Silent (SNP) | VAF 20/618 reads (3%) | catalogued as COSV100355209; called by muse, mutect2
- RIOX1 | c.1446G>A p.R482= | Silent (SNP) | VAF 58/435 reads (13%) | called by muse, mutect2, varscan2
- SHISA6 | c.1230G>A p.P410= (on ENST00000409168 / NM_001173461.1; = p.P461= on NM_207386.4) | Silent (SNP) | VAF 63/578 reads (11%) | catalogued as rs1236221763; called by muse, mutect2, varscan2
- SINHCAF | c.327T>C p.S109= | Silent (SNP) | VAF 41/290 reads (14%) | called by muse, mutect2, varscan2
- SLC9C2 | c.165T>A p.I55= | Silent (SNP) | VAF 32/208 reads (15%) | called by muse, mutect2, varscan2
- SPATC1L | c.903C>T p.A301= (on ENST00000291672 / NM_001142854.2; = p.A147= on NM_032261.5) | Silent (SNP) | VAF 91/561 reads (16%) | catalogued as rs747537035; called by muse, mutect2, varscan2
- TEX19 | c.96C>T p.S32= | Silent (SNP) | VAF 40/343 reads (12%) | catalogued as rs1033196126; called by muse, mutect2, varscan2
- TEX36 | c.456C>T p.N152= | Silent (SNP) | VAF 46/384 reads (12%) | catalogued as rs541468585, COSV64315403; called by muse, mutect2, varscan2
- ZNF649 | c.573T>G p.S191= | Silent (SNP) | VAF 53/474 reads (11%) | called by muse, mutect2, varscan2
- ZNF804B | c.954T>C p.I318= | Silent (SNP) | VAF 12/338 reads (4%) | called by muse, mutect2
- AL353804.6 | chrX:73826703 del G | 3'Flank (DEL) | VAF 17/162 reads (10%) | called by mutect2, pindel, varscan2
- DCHS2 | n.8054C>A | RNA (SNP) | VAF 39/526 reads (7%) | catalogued as COSV61772322; called by muse, mutect2
- FARP1 | c.1414+551G>A | Intron (SNP) | VAF 27/417 reads (6%) | called by muse, mutect2
